Somatic mutation profile of tumor specimen HCM-CSHL-0859-C22-01A (aliquot HCM-CSHL-0859-C22-01A-21D-A85L-36) from HCMI case HCM-CSHL-0859-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen HCM-CSHL-0859-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dfc7a59-e142-4d90-b2b4-7afcb8bf8c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0859-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0859-C22-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eecc054-97ec-46b6-ab7c-779c49e2d1a0

The open-access MAF lists 58 somatic variants for this specimen: 39 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 18, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4303C>T p.R1435* | Nonsense Mutation (SNP) | VAF 110/315 reads (35%) | catalogued as rs1568470104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 79/310 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 242/476 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- C4orf50 | c.655G>A p.A219T (on ENST00000324058; = p.A1451T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as rs758974747, COSV100135932, COSV60687321; called by muse, mutect2, varscan2
- CMYA5 | c.11779C>T p.R3927W | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372893220; called by muse, mutect2, varscan2
- CPD | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 99/359 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs781736103, COSV56716979; called by muse, mutect2, varscan2
- CROT | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 38/595 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146906054; called by muse, mutect2
- DYNC1H1 | c.13204G>A p.V4402M | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.352); catalogued as rs977186240, COSV64134521, COSV64135406; called by muse, varscan2
- HCFC1 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 212/384 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs1057524502, COSV100130176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEATR1 | c.3908A>G p.H1303R | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs745448080; called by muse, mutect2, varscan2
- L3MBTL1 | c.2123G>A p.R708Q (on ENST00000418998 / NM_001377303.1; = p.R618Q on NM_015478.7) | Missense Mutation (SNP) | VAF 127/378 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs867846143, COSV64230102; called by muse, mutect2, varscan2
- MARK1 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 56/351 reads (16%) | catalogued as COSV65066674; called by muse, mutect2, varscan2
- MB21D2 | c.1299C>G p.S433R | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV66665194; called by muse, mutect2, varscan2
- MOCS3 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 100/421 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs550877609, COSV99724225; called by muse, mutect2, varscan2
- PRKCG | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 114/496 reads (23%) | catalogued as COSV54730786; called by muse, mutect2, varscan2
- RCC1L | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 84/669 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.224); catalogued as COSV57320223; called by muse, mutect2, varscan2
- ROBO2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs746238322, COSV59903872; called by muse, mutect2, varscan2
- SDK1 | c.4615G>A p.V1539I | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs374321407; called by muse, mutect2, varscan2
- SENP7 | c.2480+1G>A p.X827_splice | Splice Site (SNP) | VAF 44/145 reads (30%) | catalogued as rs1316113359, COSV100053526; called by muse, mutect2, varscan2
- TBX5 | c.1178T>A p.L393Q | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV59861959; called by muse, mutect2, varscan2
- TTBK1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 311/636 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52488911; called by muse, mutect2, varscan2
- ZNF668 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 170/721 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770364347, COSV100336619, COSV100336986; called by muse, mutect2, varscan2
- CTSG | c.342G>C p.L114= | Splice Region (SNP) | VAF 95/349 reads (27%) | called by muse, mutect2, varscan2
- FFAR2 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 138/472 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FSIP2 | c.18745A>C p.I6249L | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- GRIP1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HSPA4L | c.1085T>A p.I362K | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- IGSF3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MYOM2 | c.1797_1802del p.T600_S601del | In Frame Del (DEL) | VAF 116/379 reads (31%) | called by mutect2, pindel, varscan2
- NDUFS6 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PZP | c.3059G>T p.R1020I | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RBFA | c.218A>T p.K73M | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SESN2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 43/282 reads (15%) | called by muse, mutect2, varscan2
- SIK2 | c.86del p.G29Afs*6 | Frame Shift Del (DEL) | VAF 197/512 reads (38%) | called by mutect2, pindel, varscan2
- SSBP1 | c.105A>T p.L35F | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SYTL4 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2
- TOP2A | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 90/380 reads (24%) | called by mutect2, varscan2
- UNC93B1 | c.163del p.R55Afs*32 | Frame Shift Del (DEL) | VAF 74/582 reads (13%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.4086_4087del p.Y1362* | Frame Shift Del (DEL) | VAF 91/442 reads (21%) | called by pindel, varscan2
- A1BG | c.1152G>T p.G384= | Silent (SNP) | VAF 165/640 reads (26%) | catalogued as rs1174452912, COSV54051087; called by muse, mutect2, varscan2
- ABCA12 | c.4950C>T p.Y1650= (on ENST00000272895 / NM_173076.3; = p.Y1332= on NM_015657.3) | Silent (SNP) | VAF 71/265 reads (27%) | catalogued as rs371166748, CM1511268, COSV55948013; called by muse, mutect2, varscan2
- CEP97 | c.442C>T p.L148= | Silent (SNP) | VAF 39/240 reads (16%) | called by muse, mutect2, varscan2
- CMPK2 | c.867C>T p.G289= | Silent (SNP) | VAF 122/470 reads (26%) | catalogued as rs1401947028; called by muse, mutect2, varscan2
- COL5A1 | c.4629T>C p.G1543= | Silent (SNP) | VAF 146/394 reads (37%) | called by muse, mutect2, varscan2
- DAB2IP | c.3351C>T p.H1117= (on ENST00000408936; = p.H1089= on NM_032552.3) | Silent (SNP) | VAF 110/285 reads (39%) | catalogued as rs376673781; called by muse, mutect2, varscan2
- FSIP2 | c.14565T>A p.I4855= | Silent (SNP) | VAF 64/244 reads (26%) | called by muse, mutect2, varscan2
- GRIP1 | c.66C>T p.P22= | Silent (SNP) | VAF 36/321 reads (11%) | called by muse, mutect2, varscan2
- HS3ST4 | c.282C>A p.P94= | Silent (SNP) | VAF 183/733 reads (25%) | called by muse, mutect2, varscan2
- LPP | c.603C>G p.P201= | Silent (SNP) | VAF 88/550 reads (16%) | called by muse, mutect2, varscan2
- LY75 | c.3954T>C p.Y1318= | Silent (SNP) | VAF 57/240 reads (24%) | catalogued as rs139342011; called by muse, mutect2, varscan2
- OGA | c.2010A>G p.Q670= | Silent (SNP) | VAF 56/268 reads (21%) | catalogued as rs768126488, COSV63380868; called by muse, mutect2, varscan2
- PLEKHB2 | c.807G>A p.P269= | Silent (SNP) | VAF 82/360 reads (23%) | catalogued as rs548216063; called by muse, mutect2, varscan2
- RNF43 | c.1215G>A p.L405= | Silent (SNP) | VAF 142/426 reads (33%) | catalogued as rs1448040339; called by muse, mutect2, varscan2
- RYR2 | c.9564T>C p.S3188= | Silent (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.774C>T p.R258= | Silent (SNP) | VAF 151/672 reads (22%) | catalogued as COSV64525986, COSV64527767; called by muse, varscan2
- ZBTB40 | c.189A>T p.A63= | Silent (SNP) | VAF 63/343 reads (18%) | called by muse, mutect2, varscan2
- ZFP28 | c.12G>A p.A4= | Silent (SNP) | VAF 120/334 reads (36%) | called by mutect2, varscan2
- ELL2 | c.-94G>T | 5'UTR (SNP) | VAF 94/282 reads (33%) | called by muse, mutect2, varscan2
